Surgical pathology report (de-identified scan), TCGA case TCGA-O2-A52Q, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site Washington University - CALGB, specimen TCGA-O2-A52Q-01A (Primary Tumor).

[page 1 of 3]
Patient

Surg Path

CLINICAL HISTORY:
Hilar cancer.

GROSS EXAMINATION:

A. "Diaphragmatic nodule", received fresh for frozen section consultation is a 0.5 x 0.5 x 0.2 cm segment of yellow soft tissue which is entirely submitted AP1. The remnant is submitted as block A1.

B. "Level 11 lymph node", received fresh for frozen section consultation is an aggregate of tan-white soft tissue that measures 1.5 x 1.2 x 0.3 cm. The specimen is entirely as BFI and the closest remnant is submitted in block B1.

C. "Level 10R", received fresh for frozen section consultation that is nodule of red-tan soft tissue that measures 2.5 x 1.5 x 0.3 cm. The specimen is entirely submitted in block C1.

D. "Level 4", received fresh for frozen section consultation of the nodule of white-tan soft tissue that measures 1.8 x 1.3 x 0.4 cm. The specimen is entirely submitted DFI with the remnant is submitted in block D1.

E. "Right intrapericardial pneumonectomy", received is a lung which weighs 625 grams that measures 19 x 17 x 4.5 cm. Located immediately posterior to the hilar structures is a 6.3 x 6 x 2.5 cm white, firm, lobulated tumor situated in the upper lobe. The tumor protrudes through the medial visceral pleura to involve the pericardium and mediastinal fat. A segment of overlying pericardium that measures 5.5 x 5 cm. The tumor also causes focal retraction of the pleura laterally. The tumor encases hilar vessels, but does not grossly invade the wall. Serial sectioning does not reveal any other parenchymal lesions. Multiple hilar lymph nodes are identified. The specimen is submitted as follows:

BLOCK SUMMARY:

- E1- BFI (bronchial margin).
- E2- hilar lymph nodes and vascular margin.
- E3- upper lobe lobar lymph nodes.
- E4-E5- tumor with overlying pericardium and soft tissue margins.
- E6- tumor adjacent to hilum.
- E7- tumor with lateral pleura.
- E8- additional tumor.
- E9- uninvolved lung (lower lobe).

F. "Level 11 number two", received in formalin is a 0.6 cm nodule of tan soft tissue which is entirely submitted in block F1.

G. "4R lymph node number two", received in formalin are multiple nodules of tan soft tissue with an aggregate measurement of 2 x 1.6 x 0.2 cm. The specimen is entirely submitted in block G1.

H. "2R lymph node", received in formalin is a 0.9 cm nodule of tan soft tissue which is entirely submitted in block H1.

I. "Azygous vein", received in formalin is a nodule of tan soft tissue which measures 1.1 x 0.7 x 0.3 cm. Distal lumen is identified. The specimen is bisected and submitted entirely in block I1.

J. "Level 7 lymph node", received in formalin is a 2.3 x 1.1 x 0.4 cm lymph node, which is bisected and entirely submitted in block J1.

ICD-0-3

Carcinoma, squamous cell, NOS

8070/3

Site: lung, upper lobe C 34.1

hw

11/12/12

[page 2 of 3]
K. "Level 3 lymph node", received in formalin are multiple nodules of tan soft tissue that has an aggregate measurement of 4 x 1.5 x 0.4 cm. The specimen is entirely submitted in blocks K1-K2.

L. "Tracheal bronchial lymph node", received in formalin is a nodule of firm, white-tan soft tissue that measures 1.3 x 1.5 x 1 cm. The specimen is sectioned and submitted in blocks L1-L2.

INTRA OPERATIVE CONSULTATION:

- A. "Diaphragmatic nodule": AFI- negative for carcinoma
- B. "Level 11 lymph node": BFI- metastatic non small cell carcinoma
- C. "Level 10R": CFI- negative for carcinoma
- D. "Level 4": DFI- negative for carcinoma
- E. "Right extrapericardial pneumonectomy": EFI- bronchial margin- negative for carcinoma

MICROSCOPIC EXAMINATION:

Microscopic examination is performed.

PATHOLOGIC STAGE:

PROCEDURE: PNEUMONECTOMY, MEDIASTINAL LYMPH NODE BIOPSIES.

PATHOLOGIC STAGE (AJCC 6th Edition): pT3 pN1 pMx

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section, past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

DIAGNOSIS:

- A. "DIAPHRAGMATIC NODULE" (BIOPSY):

FIBROVASCULAR TISSUE WITH CHRONIC INFLAMMATION.
NO EVIDENCE OF MALIGNANCY.

- B. "LEVEL 11 LYMPH NODE" (BIOPSY):

METASTATIC NON-SMALL CELL CARCINOMA.

- C. "LEVEL 10R LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODES, NEGATIVE FOR MALIGNANCY.

- D. "LEVEL 4" (BIOPSY):

PROFILES OF LYMPH NODES, NEGATIVE FOR MALIGNANCY.

- E. "RIGHT INTRAPERICARDIAL PNEUMONECTOMY":

CARCINOMA OF LUNG:

[page 3 of 3]
Histologic type: SQUAMOUS CARCINOMA
Histologic grade: POORLY DIFFERENTIATED

Extent of invasion
- Max. tumor diameter: 6.3 CM
- Mainstem bronchus: NEGATIVE
- Visceral pleura: POSITIVE
- Chest wall: NEGATIVE
- Mediastinum: NEGATIVE
- Parietal pericardium: POSITIVE, NON-TRANSMURAL
- >1 tumor nodules? NEGATIVE
- Panlobar atelectasis? NEGATIVE

Margins
- Bronchial: NEGATIVE
- Vascular: NEGATIVE
- Parenchymal: NEGATIVE
- Pleural: NEGATIVE

Other prognostic features
- Vascular invasion: POSITIVE

Regional lymph nodes: METASTATIC CARCINOMA PRESENT IN 3 OF 10 LYMPH
NODES (3/10).

Additional findings: MILD CENTRILOBULAR EMPHYSEMA.

F. "LEVEL 11 NUMBER TWO" (BIOPSY):

ADIPOSE TISSUE, NO LYMPH NODES ARE IDENTIFIED.
NO EVIDENCE OF MALIGNANCY.

G. "4R LYMPH NODE NUMBER TWO" (BIOPSY):

PROFILES OF LYMPH NODES, NEGATIVE FOR MALIGNANCY.

H. "2R LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODE, NEGATIVE FOR MALIGNANCY.

I. "AZYGOUS VEIN" (BIOPSY):

FIBROVASCULAR TISSUE WITH ARTERY AND VEIN, NO EVIDENCE OF MALIGNANCY.

J. "LEVEL 7 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODES, NEGATIVE FOR MALIGNANCY.

K. "LEVEL 3 LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODES, NEGATIVE FOR MALIGNANCY.

L. "TRACHEAL BRONCHIAL LYMPH NODE" (BIOPSY):

PROFILES OF LYMPH NODES, NEGATIVE FOR MALIGNANCY.

I certify that I personally conducted the diagnostic evaluation of the above
specimen(s) and have rendered the above diagnosis(es).

Reviewed Initials: JAL	Date Reviewed: 11/9/18	11/21/18

Source: NCI Genomic Data Commons file 23bb0645-a273-4edf-b484-ffbcd8eb1702 (TCGA-O2-A52Q.9B7C77F8-7EFE-4598-8273-7C902EA77C55.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).